CCDI case PBCINB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a5f576d-d586-4e17-9311-84b99b4d1740

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,837 days).

Biospecimens (3 samples)
- Sample 0DT4HW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT4I5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT4I9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
